Gene-level copy-number profile of tumor specimen TCGA-DJ-A13M-01A from TCGA case TCGA-DJ-A13M, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.8 years (10,530 days).
Specimen TCGA-DJ-A13M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THCA.8bf6bb16-8628-42ab-8e0a-c026eb1fca00.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DJ-A13M-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90da7dd0-12ac-4136-a734-4274dd91b818

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,376; copy number 2: 58,327; copy number 3: 117.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DJ-A13M-01A-11D-A10T-01): tumor purity 0.88, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,376. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
